Gene-level copy-number profile of tumor specimen TCGA-94-7943-01A from TCGA case TCGA-94-7943, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 80.2 years (29,282 days).
Specimen TCGA-94-7943-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.6dc1f7ac-ac9c-4b8a-a41d-231271cdae00.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-94-7943-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/942107c2-20b4-4a46-824b-7526b756dd54

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 84; copy number 1: 101; copy number 2: 21,035; copy number 3: 14,680; copy number 4: 17,877; copy number 5: 2,141; copy number 6: 2,473; copy number 7: 104; copy number 8: 142; copy number 9: 968; copy number 10: 13; copy number 11: 16; copy number 12: 13; copy number 13: 21; copy number 16: 6; copy number 19: 32; copy number 22: 79; copy number 25: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-94-7943-01A-11D-2183-01): tumor purity 0.58, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,488,300–11,771,350, 5 genes (within-gene range 0–2): AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3.
- chr9:19,789,179–23,672,399, 79 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,037 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:163,769,339–164,921,629, 13 genes, copy number 5: AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7.
- chr2:38,814–65,432,637, 1,074 genes, copy number 5–7 (broad region; genes not listed).
- chr2:65,439,838–65,512,076, 3 genes, copy number 5: AC012370.2, DNAJB12P1, RPS15AP15.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 6–9 (broad region; genes not listed).
- chr5:29,795,938–45,895,970, 264 genes, copy number 5 (broad region; genes not listed).
- chr6:35,041,116–47,042,350, 305 genes, copy number 5 (broad region; genes not listed).
- chr6:169,702,190–170,738,536, 33 genes, copy number 5: C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1, AL603783.1, AL596442.4, AL596442.3, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1, PSMB1, TBP, PDCD2, AL031259.1, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr8:33,436,268–38,704,855, 100 genes, copy number 5–19 (broad region; genes not listed).
- chr8:100,572,889–128,564,679, 376 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:132,775,358–133,326,404, 11 genes, copy number 5: PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1.
- chr8:135,859,369–140,458,579, 23 genes, copy number 5 (within-gene range 3–5): LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13.
- chr11:65,422,774–65,574,198, 19 genes, copy number 6: NEAT1, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B.
- chr11:126,160,714–128,241,441, 35 genes, copy number 5: AP001893.3, AP001893.2, RPUSD4, AP001893.1, FAM118B, RNU4-86P, RN7SL351P, SRPRA, FOXRED1, RPL35AP26, TIRAP, AP001318.1, AP001318.2, DCPS, GSEC, ST3GAL4, AP001318.3, KIRREL3, KIRREL3-AS1, AP001783.1, AP002833.1, AP002833.3, KIRREL3-AS2, MIR3167, AP002833.2, KIRREL3-AS3, AP001993.1, AP003121.1, LINC02712, RN7SKP121, RN7SKP279, AP003532.1, DNAJB6P1, LINC02725, LINC02098.
- chr12:16,347,142–16,609,259, 4 genes, copy number 5 (within-gene range 4–5): MGST1, SUPT16HP1, AC007528.1, AC007552.1.
- chr12:44,498,616–47,706,030, 54 genes, copy number 5–8 (within-gene range 3–8): AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156, ADI1P3, AC003686.1, AC004486.1, RPAP3.
- chr14:35,756,327–35,767,110, 2 genes, copy number 5: AL137818.1, QRSL1P3.
- chr15:66,860,303–66,956,518, 3 genes, copy number 5: AC110048.2, AC093334.1, LINC02206.
- chr15:67,000,814–67,001,085, 1 gene, copy number 5: HMGN2P47.
- chr15:86,079,973–87,029,052, 1 gene, copy number 5 (within-gene range 4–5): AGBL1.
- chr15:86,630,266–87,703,852, 8 genes, copy number 5: AC012229.1, AC016987.2, AC016987.1, AC078905.1, AC020687.1, RNU6-185P, LINC00052, AC103871.1.
- chr17:8,878,911–40,457,725, 1,103 genes, copy number 6–25 (within-gene range 4–25) (broad region; genes not listed).
- chr18:11,851,413–11,929,476, 7 genes, copy number 5: CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3.
- chr19:11,538,767–11,980,617, 24 genes, copy number 6 (within-gene range 3–6): CNN1, ELOF1, ZNF627, ACP5, GAPDHP76, AC008543.1, ZNF887P, HNRNPA1P10, ZNF833P, ZNF823, AC008543.3, AC008543.2, ZNF441, AC008543.5, ZNF491, ZNF440, AC008543.4, ZNF439, AC020951.1, ZNF69, ZNF700, AC008770.2, AC008770.3, ZNF763.
- chr19:11,996,809–11,996,916, 1 gene, copy number 6: RNA5SP464.
- chr19:27,638,483–45,651,805, 754 genes, copy number 5–11 (broad region; genes not listed).
- chr20:50,162,765–50,691,542, 19 genes, copy number 5 (within-gene range 4–5): LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1.

Autosomal genes at a single copy (total copy number 1): 101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
